Somatic mutation profile of tumor specimen TARGET-10-PARIZN-09A (aliquot TARGET-10-PARIZN-09A-01D) from TARGET case TARGET-10-PARIZN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.2 years (3,724 days).
Specimen TARGET-10-PARIZN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 031421a5-6eba-4b27-add7-9c1df2c3d579.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARIZN-10A (Blood Derived Normal), aliquot TARGET-10-PARIZN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8baa3fdf-6596-4334-9c2d-877e6564f65b

The open-access MAF lists 30 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Intron 4, 3'UTR 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 31/56 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 43/92 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- ADAM10 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs200668065, COSV53049366; called by muse, mutect2, varscan2
- CSMD2 | c.9470G>A p.R3157H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs753503294, COSV53881918; called by muse, mutect2, varscan2
- CYP19A1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759563175, CM994538, COSV53057292; called by muse, mutect2, varscan2
- EPHB2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs200298851, COSV65860078; called by muse, mutect2, varscan2
- ERG | c.1108G>A p.D370N (on ENST00000398919 / NM_001243428.1; = p.D346N on NM_004449.4) | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55727362; called by muse, mutect2, varscan2
- HLX | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65044345; called by muse, mutect2, varscan2
- HP1BP3 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs765712174, COSV56561393; called by muse, mutect2, varscan2
- MUC17 | c.10403C>T p.T3468M | Missense Mutation (SNP) | VAF 172/342 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs763016905, COSV60280694; called by muse, mutect2, varscan2
- NOTCH1 | c.7448C>T p.T2483M | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53029938; called by muse, mutect2, varscan2
- NOTCH1 | c.4775T>C p.F1592S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024854, COSV53033159; called by muse, mutect2, varscan2
- RAC2 | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV50773841; called by muse, mutect2, varscan2
- RHBDF1 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as rs909485672, COSV51953581; called by muse, mutect2, varscan2
- ZFP82 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 79/159 reads (50%) | catalogued as COSV67564673; called by muse, mutect2, varscan2
- CCDC30 | c.1656del p.V553Sfs*10 (on ENST00000340612; = p.V510Sfs*10 on NM_001080850.3) | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | called by mutect2, pindel, varscan2
- AC008676.3 | c.171G>A p.T57= | Silent (SNP) | VAF 70/148 reads (47%) | catalogued as rs746101731, COSV56635988; called by muse, mutect2, varscan2
- FSCN2 | c.486C>T p.A162= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs375636321; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPC5 | c.1659G>A p.A553= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs761812897, COSV65629097; called by muse, mutect2, varscan2
- MMP17 | c.1179C>T p.S393= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs200341756, COSV62179405; called by muse, mutect2, varscan2
- MOGAT3 | c.582G>A p.A194= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- SIDT2 | c.813C>T p.V271= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs377458681; called by muse, mutect2, varscan2
- SLC4A3 | c.2028G>T p.L676= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- TUBB2A | c.1293C>T p.D431= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as rs756141916, COSV61318835; called by muse, mutect2, varscan2
- GUCY1A2 | c.1207-16054C>T | Intron (SNP) | VAF 18/24 reads (75%) | catalogued as rs750036468; called by muse, mutect2, varscan2
- IFT172 | c.1325+33C>T | Intron (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2
- RAB40AL | c.*28A>G | 3'UTR (SNP) | VAF 23/24 reads (96%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5544+106C>A | Intron (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.2332+100G>A | Intron (SNP) | VAF 38/87 reads (44%) | catalogued as rs919103763; called by muse, mutect2, varscan2
- ZNF398 | c.*6A>T | 3'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
